TARGET case TARGET-30-PASKPC — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/808ceeac-d0b1-51e5-89a8-637fe41b5156

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Age at diagnosis: 2.6 years (964 days); Year of diagnosis: 2009; Days to last follow up: 2,210 days (6.1 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 3; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 2,210 days (6.1 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,210; Year of follow up: 2015.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Biospecimens (2 samples)
- Sample TARGET-30-PASKPC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASKPC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 2210
- Protocol: ANBL00B1, ANBL0032
- Histology: Unfavorable
- ICDO: C80.9
